MMRF case MMRF_2087 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/48fed608-6018-452b-8f33-0881dd43abc1

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 283 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.4 years (27,166 days); ISS stage: II; Days to last known disease status: 283 days; Days to last follow up: 283 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 165 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 26 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 58 days; Days to treatment end: 86 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 103 days; Days to treatment end: 130 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 131 days; Days to treatment end: 198 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 165 days; Days to treatment end: 198 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 166 days; Days to treatment end: 198 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 208 days; Days to treatment end: 249 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 208 days; Days to treatment end: 229 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 230 days; Days to treatment end: 261 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 249 days; Days to treatment end: 256 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 256 days; Days to treatment end: 261 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 283.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 18 (ECOG 2): M Protein 3.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.752 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 56 mg/dL; Immunoglobulin G 37.4 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 5.03 µg/mL; Hemoglobin 5.46 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 8.6 g/dL; Glucose 10.7 mmol/L.
- Day 103 (ECOG 2): M Protein 1.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.552 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.1 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 9.57 mmol/L.
- Day 190 (ECOG 2): M Protein 2.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.001 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 77.4 mg/dL; Immunoglobulin G 31.9 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 5.58 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.05 mmol/L; Albumin 28 g/L; Total Protein 6.6 g/dL; Glucose 17.4 mmol/L.

Other clinical attributes
- Day 18: Weight: 63 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_2087_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 18 days.
- Sample MMRF_2087_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 18 days.
- Sample MMRF_2087_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 190 days.
